Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A50E, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A50E-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Cervical Tumor is ill - margins occupying cervix and invasion of uterus, with 10x8x8cm in size, solid and firm and white-gray surface.

Bladder wall and rectal wall are infiltrated by tumor to form masses with 6x4x4 and 4x3x3cm, prospectively. Cervical Tumor is ill - margins occupying cervix and invasion of uterus, with 10x8x8cm in size, solid and firm and white-gray surface.

Bladder wall and rectal wall are infiltrated by tumor to form masses with 6x4x4 and 4x3x3cm, prospectively.

Microscopic Description: Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells connecting each other. The malignant cells have relatively moderate, light eosinophilic or keratinized cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor is invasion of completely cervical thickness and invading bladder or lymph nodes. Tumor is necrotic and invasion of lymphocytes. Transitional cell are benign.

Diagnosis Details: Squamous cell carcinoma, large cell, non-keratinizing, invading stromal tissue of cervix

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 10 x 8 x 8 cm

Histologic type: Squamous cell carcinoma, large cell, non-keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Lesion greater than 4.0 cm

Lymph nodes: 6/6 positive for metastasis (Bilateral pelvic lymph node 6/6)

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

ICD-0-3

carcinoma, squamous cell, large cell,
non-keratinizing 8072/3
Site: cervix, NOS C53.9

hw
10/29/12

[page 2 of 2]
Additional pathologic findings: Not specified

Comments: None

10/29/12

Histology Discrepancy		X
Reviewer (Print)	Date Reviewed: 10/29/12	

Source: NCI Genomic Data Commons file 4e588ed8-4a1b-4522-ade4-e66144e4054a (TCGA-EA-A50E.9AF109CD-57A9-4560-8B36-9977F208AEE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).